Somatic mutation profile of tumor specimen TCGA-KK-A7AU-01A (aliquot TCGA-KK-A7AU-01A-11D-A32B-08) from TCGA case TCGA-KK-A7AU, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.3 years (23,118 days).
Specimen TCGA-KK-A7AU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 913a4293-f3af-486b-b86e-733e9648d415.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A7AU-11A (Solid Tissue Normal), aliquot TCGA-KK-A7AU-11A-11D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ddfecee-6aa2-48c4-85ba-25b1743b4ae9

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.920-1G>T p.X307_splice | Splice Site (SNP) | VAF 39/55 reads (71%) | hotspot (GDC flag); catalogued as rs587781702, CS0910927, CS114009, COSV52664150, COSV52690279, COSV52737535; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCDC32 | c.131T>G p.V44G | Missense Mutation (SNP) | VAF 28/287 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.054); catalogued as COSV100785918; called by muse, mutect2
- CEP192 | c.3542C>G p.S1181* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as rs759638699, COSV100380913, COSV58063820; called by muse, mutect2, varscan2
- DBH | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs763373839, COSV99707988; called by muse, mutect2, varscan2
- FAT4 | c.10242G>C p.Q3414H | Missense Mutation (SNP) | VAF 93/194 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs371194603; called by muse, mutect2, varscan2
- FCRL1 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.631); catalogued as COSV63824536, COSV63826643; called by muse, mutect2, varscan2
- FLT1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs766436940, COSV56719777, COSV56738177; called by muse, mutect2, varscan2
- KMT2B | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs202218975, COSV99385946; called by muse, varscan2
- MYBL2 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); catalogued as rs748992937, COSV53833877; called by muse, mutect2, varscan2
- PDP1 | c.112T>C p.Y38H | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs910786213, COSV52602322; called by muse, mutect2, varscan2
- POLR2B | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288589258, COSV100107961; called by muse, mutect2, varscan2
- SV2A | c.427A>G p.K143E | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV100975080; called by muse, mutect2, varscan2
- VIRMA | c.1700A>C p.K567T | Missense Mutation (SNP) | VAF 209/342 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.654); catalogued as COSV99888035; called by muse, mutect2, varscan2
- ZNF648 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100374489, COSV99046079; called by muse, mutect2
- LIMK1 | c.982T>C p.C328R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- ACTRT2 | c.927C>T p.H309= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as rs762908845, COSV65760724; called by muse, mutect2, varscan2
- ADGRV1 | c.8064C>T p.S2688= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs75195840; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP2B3 | c.1425G>A p.T475= | Silent (SNP) | VAF 80/87 reads (92%) | catalogued as rs373112886, COSV54853349, COSV99683837; called by muse, mutect2, varscan2
- CAPN3 | c.792C>T p.C264= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as COSV100532723; called by muse, mutect2, varscan2
- LCT | c.1933C>T p.L645= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV99929026; called by muse, mutect2
- RECQL | c.1395A>G p.V465= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99556439, COSV99556691; called by muse, mutect2
